CCDI case PBBPEH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/257f2565-220d-4181-ac47-0de18d6ef68d

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 3.3 years (1,217 days).

Biospecimens (2 samples)
- Sample 0DDRO6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDROD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
